Gene-level copy-number profile of tumor specimen C3L-01327-01 from CPTAC case C3L-01327, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.4 years (27,160 days).
Specimen C3L-01327-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a5a1213d-1b47-4c46-9c1f-3f0413ec9441.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01327-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/e184186c-7317-44e9-ae05-d8cea15a0e33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 5,349; copy number 2: 46,351; copy number 3: 7,083; copy number 4: 19; copy number 5: 60; copy number 9: 3; copy number 51: 24; copy number 52: 1; copy number 104: 7.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:130,213,488–130,483,193, 1 gene (within-gene range 0–1): LINC02646.
- chr10:130,505,106–130,505,201, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 95 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:179,097,731–180,037,053, 27 genes, copy number 5: Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1.
- chr3:181,699,608–181,699,883, 1 gene, copy number 5 (within-gene range 3–5): AC117415.1.
- chr3:181,847,526–183,428,778, 26 genes, copy number 5: AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151.
- chr3:183,613,620–183,616,742, 1 gene, copy number 5: AC068769.1.
- chr7:54,752,250–55,572,988, 11 genes, copy number 5–104: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:55,764,797–56,323,601, 26 genes, copy number 5–51: PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1.
- chr8:7,768,977–7,795,870, 3 genes, copy number 9: FAM90A10P, PRR23D2, PRR23D3P.

Autosomal genes at a single copy (total copy number 1): 2,496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
